Somatic mutation profile of tumor specimen TCGA-G9-6384-01A (aliquot TCGA-G9-6384-01A-11D-1786-08) from TCGA case TCGA-G9-6384, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 53.7 years (19,620 days).
Specimen TCGA-G9-6384-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be890aa9-4d2a-420c-94fd-19f7b03f5336.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6384-10A (Blood Derived Normal), aliquot TCGA-G9-6384-10A-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f276832-6f99-4889-a16b-4e2d9d55e399

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, Nonsense Mutation 2, Splice Region 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER3 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1427615126, COSV58471081; called by muse, mutect2, varscan2
- ARHGAP36 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs373442691, COSV52273566; called by muse, mutect2, varscan2
- CADM2 | c.1136T>G p.F379C (on ENST00000407528 / NM_001167674.2; = p.F381C on NM_153184.4) | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67411448; called by muse, mutect2
- CD1B | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 25/167 reads (15%) | catalogued as rs370440810; called by muse, mutect2, varscan2
- CLK3 | c.1048A>G p.I350V (on ENST00000395066 / NM_001130028.1; = p.I202V on NM_003992.4) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.223); catalogued as rs1252436855, COSV61415322; called by muse, mutect2
- DLAT | c.305C>G p.T102R | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs782730028; called by muse, mutect2
- GSDMD | c.684C>T p.D228= | Splice Region (SNP) | VAF 4/18 reads (22%) | catalogued as rs201583128; called by mutect2, varscan2
- HTR5A | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs749047238, COSV55288043; called by muse, mutect2, varscan2
- KATNIP | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as rs1567450023, COSV55194240; called by muse, mutect2, varscan2
- KNDC1 | c.2114G>T p.G705V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV58848638; called by mutect2, varscan2
- LRRC47 | c.1700C>G p.P567R | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65561933, COSV65562148; called by muse, mutect2, varscan2
- NRAP | c.3409G>T p.D1137Y (on ENST00000359988 / NM_001322945.2; = p.D1102Y on NM_006175.4) | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV63494767; called by muse, mutect2, varscan2
- PCDHA6 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.966); catalogued as rs782446908, COSV65341958; called by muse, mutect2, varscan2
- PCDHGB3 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs376897075; called by muse, mutect2, varscan2
- PCLO | c.3037G>C p.E1013Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV61676461; called by muse, mutect2, varscan2
- PLXNA2 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs746356521, COSV65444856; called by muse, varscan2
- PRRX1 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs767923329, CM143960, COSV53420192; called by muse, mutect2, varscan2
- RASGRF1 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV69184052; called by muse, mutect2
- SPAG17 | c.4333G>C p.D1445H | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60470639; called by muse, mutect2, varscan2
- USP16 | c.851A>G p.Q284R | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57628486; called by muse, mutect2
- PSPC1 | c.108del p.M37Wfs*122 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- ATP10B | c.3093G>T p.T1031= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as COSV59167345; called by muse, mutect2, varscan2
- FAM174A | c.96C>T p.V32= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV57066246; called by muse, mutect2
- THEG | c.291G>A p.E97= | Silent (SNP) | VAF 39/228 reads (17%) | catalogued as COSV61073353; called by muse, mutect2, varscan2
- ZNF689 | c.276T>G p.A92= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV54910351; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501251 del AT | 5'Flank (DEL) | VAF 6/48 reads (13%) | catalogued as rs751290649; called by pindel, varscan2
